Somatic mutation profile of tumor specimen TCGA-5P-A9K2-01A (aliquot TCGA-5P-A9K2-01A-11D-A42J-10) from TCGA case TCGA-5P-A9K2, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 62.9 years (22,964 days).
Specimen TCGA-5P-A9K2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 989c941a-2662-4e95-bbe4-d00d07e7f339.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5P-A9K2-10A (Blood Derived Normal), aliquot TCGA-5P-A9K2-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d40c77c-ea4b-4097-8ac7-887d07b4d51e

The open-access MAF lists 70 somatic variants for this specimen: 55 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 14, Frame Shift Del 8, Nonsense Mutation 2, Intron 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSS1 | c.432-2A>G p.X144_splice | Splice Site (SNP) | VAF 20/62 reads (32%) | catalogued as COSV100053788; called by muse, mutect2, varscan2
- ADARB1 | c.1285T>G p.S429A | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.8); PolyPhen benign (0.038); catalogued as COSV100653870; called by muse, mutect2, varscan2
- AGFG1 | c.191G>T p.R64M | Missense Mutation (SNP) | VAF 208/492 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100028855; called by muse, mutect2, varscan2
- ANKLE2 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100513929, COSV100514177; called by muse, mutect2, varscan2
- ASH1L | c.760A>G p.I254V | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.014); catalogued as COSV64212125; called by muse, mutect2, varscan2
- BAZ2B | c.1449C>G p.F483L | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.437); catalogued as COSV100600701; called by muse, mutect2, varscan2
- CAD | c.5513G>T p.R1838L | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV53030438, COSV99255928; called by muse, mutect2, varscan2
- CCDC144A | c.4096A>G p.K1366E | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.159); catalogued as COSV100138578; called by muse, mutect2, varscan2
- CTR9 | c.1828G>A p.V610M | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs1245642519, COSV100797380; called by muse, mutect2, varscan2
- CYFIP1 | c.2852C>T p.T951M | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs1424755801, COSV100488328; called by muse, mutect2, varscan2
- EHBP1L1 | c.923A>G p.K308R | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV100499906; called by muse, mutect2, varscan2
- ERF | c.40T>C p.W14R | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99724687; called by muse, mutect2, varscan2
- FAM120AOS | c.413T>G p.F138C | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99465667; called by muse, mutect2, varscan2
- FIP1L1 | c.221C>G p.P74R | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.027); catalogued as COSV100184468; called by muse, mutect2, varscan2
- FRYL | c.2471A>G p.Y824C | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs544935208, COSV99977080; called by muse, mutect2, varscan2
- GASK1B | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1223992577, COSV99647721; called by muse, mutect2, varscan2
- GLT6D1 | c.715A>G p.I239V | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1159193062, COSV100874542; called by muse, mutect2, varscan2
- GRAMD2B | c.419A>G p.Q140R | Missense Mutation (SNP) | VAF 83/202 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99587104; called by muse, mutect2, varscan2
- HLA-C | c.10A>G p.M4V | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.025); catalogued as COSV100880604; called by muse, mutect2, varscan2
- IP6K2 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.963); catalogued as rs372776558, COSV99583671; called by muse, mutect2
- ITGAV | c.303A>C p.E101D | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.049); catalogued as COSV99655052; called by muse, mutect2, varscan2
- KLC4 | c.1457T>A p.L486Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99432058; called by muse, mutect2, varscan2
- LY75-CD302 | c.5407A>G p.K1803E | Missense Mutation (SNP) | VAF 187/451 reads (41%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.582); catalogued as COSV99374508; called by muse, mutect2, varscan2
- MTF1 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100888647; called by muse, mutect2, varscan2
- PAPPA | c.1546T>A p.F516I | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100074328; called by muse, mutect2, varscan2
- RGS3 | c.1566C>A p.H522Q (on ENST00000350696 / NM_001282923.2; = p.H410Q on NM_017790.4) | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as COSV100465392; called by muse, mutect2, varscan2
- RIMS1 | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV99327427; called by muse, mutect2, varscan2
- RSAD1 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 63/110 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99364078; called by muse, mutect2, varscan2
- SAFB2 | c.2844C>A p.H948Q | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV99385780; called by muse, mutect2, varscan2
- SF3B1 | c.1382C>A p.S461Y | Missense Mutation (SNP) | VAF 96/215 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100134845; called by muse, mutect2, varscan2
- SLC25A11 | c.814T>A p.Y272N | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99337401; called by muse, mutect2, varscan2
- SLC4A8 | c.160A>G p.M54V | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100177020; called by muse, mutect2, varscan2
- TAT | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1401035465, COSV63532436, COSV63532788; called by muse, mutect2, varscan2
- TET1 | c.2054T>A p.L685* | Nonsense Mutation (SNP) | VAF 99/245 reads (40%) | catalogued as COSV101018348; called by muse, mutect2, varscan2
- TNFRSF14 | c.334T>C p.S112P | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100859163; called by muse, mutect2, varscan2
- TTYH1 | c.128C>A p.A43D | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781523440, COSV100002110; called by muse, mutect2, varscan2
- USP12 | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99997637; called by muse, mutect2, varscan2
- WDR25 | c.1459T>A p.L487M | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.876); catalogued as COSV100091885; called by muse, mutect2, varscan2
- WNK1 | c.6752A>C p.H2251P (on ENST00000315939 / NM_018979.4; = p.H2003P on NM_014823.3) | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99942590; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2411G>C p.S804T | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV99648674; called by muse, mutect2, varscan2
- ZCCHC14 | c.2344C>T p.P782S (on ENST00000268616; = p.P919S on NM_015144.3) | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.609); catalogued as COSV99234037; called by muse, mutect2, varscan2
- ZNF184 | c.949C>A p.Q317K | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.149); catalogued as COSV99279705; called by muse, mutect2, varscan2
- ZNF207 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs1437091394, COSV58301288; called by muse, mutect2, varscan2
- ZNF221 | c.23T>G p.L8R | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.933); catalogued as COSV99240765; called by muse, mutect2, varscan2
- ZNF394 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 14/23 reads (61%) | catalogued as COSV100529905; called by muse, mutect2, varscan2
- ZNF709 | c.779C>G p.A260G | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV101172204; called by muse, mutect2, varscan2
- ABCB11 | c.3409del p.V1137* | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | called by mutect2, pindel, varscan2
- ABHD16B | c.1237del p.E413Rfs*18 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | called by mutect2, pindel, varscan2
- CDKN2AIP | c.144del p.A49Lfs*61 | Frame Shift Del (DEL) | VAF 53/155 reads (34%) | called by mutect2, pindel, varscan2
- DENND5A | c.3266del p.I1089Tfs*15 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- HELZ2 | c.845del p.N282Ifs*33 | Frame Shift Del (DEL) | VAF 41/89 reads (46%) | called by mutect2, pindel, varscan2
- LRRC36 | c.1485_1486del p.G496Qfs*6 | Frame Shift Del (DEL) | VAF 32/114 reads (28%) | called by mutect2, pindel, varscan2
- RREB1 | c.5059_5063del p.E1687Tfs*30 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- TAS1R3 | c.1419del p.R473Sfs*11 | Frame Shift Del (DEL) | VAF 35/102 reads (34%) | called by mutect2, pindel, varscan2
- WDR18 | c.1136_1138del p.L379del | In Frame Del (DEL) | VAF 20/46 reads (43%) | called by mutect2, pindel, varscan2
- ADGRB2 | c.3513C>T p.A1171= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as rs140842802; called by muse, mutect2
- BIRC2 | c.585A>G p.P195= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs753726394, COSV99926726; called by muse, mutect2, varscan2
- CCDC144A | c.4095G>A p.L1365= | Silent (SNP) | VAF 34/164 reads (21%) | catalogued as COSV100138576; called by muse, mutect2, varscan2
- CELSR2 | c.4824C>T p.S1608= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV99604000; called by muse, mutect2
- CNOT3 | c.1377C>G p.S459= | Silent (SNP) | VAF 58/146 reads (40%) | catalogued as rs769897893, COSV99651936, COSV99652238; called by muse, mutect2, varscan2
- DDC | c.1032T>C p.T344= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV100779434; called by muse, mutect2, varscan2
- FAM81B | c.1038T>C p.S346= | Silent (SNP) | VAF 159/368 reads (43%) | catalogued as COSV99352907; called by muse, mutect2, varscan2
- FLRT2 | c.495T>C p.F165= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV100420493; called by muse, mutect2, varscan2
- GZF1 | c.42A>C p.P14= | Silent (SNP) | VAF 28/39 reads (72%) | catalogued as COSV100582566; called by muse, mutect2, varscan2
- IARS2 | c.255G>T p.L85= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100228369; called by muse, mutect2, varscan2
- NOP53 | c.103A>C p.R35= | Silent (SNP) | VAF 65/161 reads (40%) | catalogued as COSV99621999; called by muse, mutect2, varscan2
- POU3F2 | c.1083C>A p.I361= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as rs749593813, COSV100099224; called by muse, mutect2, varscan2
- PRDM5 | c.141C>T p.D47= | Silent (SNP) | VAF 68/151 reads (45%) | catalogued as COSV99309751, COSV99310726; called by muse, mutect2, varscan2
- THRAP3 | c.141T>G p.S47= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV100663415; called by muse, mutect2, varscan2
- SARS1 | c.1257+323_1257+336del | Intron (DEL) | VAF 32/113 reads (28%) | called by mutect2, pindel, varscan2
